Somatic mutation profile of tumor specimen ALCH-B1UY-TTP1-A (aliquot ALCH-B1UY-TTP1-A-2-0-D-A76B-36) from ALCHEMIST case ALCH-B1UY, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 70.6 years (25,781 days).
Specimen ALCH-B1UY-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7e8e02e8-6d73-4116-9fa6-71be26a87a26.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1UY-NB1-A (Blood Derived Normal), aliquot ALCH-B1UY-NB1-A-1-0-D-A76B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/34b7d254-1d2d-4ed9-98a0-807fbe65ae63

The open-access MAF lists 484 somatic variants for this specimen: 351 protein-altering or splice-affecting, 69 silent, 64 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 297, Silent 69, Nonsense Mutation 27, Intron 26, Frame Shift Del 14, RNA 14, 5'UTR 9, 5'Flank 7, Splice Site 6, 3'UTR 5, Splice Region 4, 3'Flank 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HSF4 | c.341T>C p.L114P | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs121909048, CM021279; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 76/343 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PRF1 | c.445G>A p.G149S | Missense Mutation (SNP) | VAF 54/332 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as rs147462227, CM023668, CM080507; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A2M | c.2767T>C p.S923P | Missense Mutation (SNP) | VAF 25/146 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.786); catalogued as rs1256595612, COSV59389799; called by muse, mutect2, varscan2
- ADAM29 | c.2245C>T p.Q749* | Nonsense Mutation (SNP) | VAF 32/216 reads (15%) | catalogued as rs1256645547; called by muse, mutect2, varscan2
- ADGRG4 | c.3631G>A p.D1211N | Missense Mutation (SNP) | VAF 49/119 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV54965445; called by muse, mutect2, varscan2
- ADPRH | c.563C>A p.P188H | Missense Mutation (SNP) | VAF 70/272 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV100813303; called by muse, mutect2, varscan2
- AHCTF1 | c.890G>C p.S297T (on ENST00000366508; = p.S271T on NM_015446.5) | Missense Mutation (SNP) | VAF 87/253 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.107); catalogued as rs1015121343; called by muse, mutect2, varscan2
- AJAP1 | c.1043C>G p.T348R | Missense Mutation (SNP) | VAF 82/330 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65452314; called by muse, mutect2, varscan2
- AMOTL1 | c.637del p.A213Rfs*24 | Frame Shift Del (DEL) | VAF 5/21 reads (24%) | catalogued as rs1263019457; called by mutect2, pindel, varscan2
- ATXN2 | c.3514C>T p.Q1172* (on ENST00000550104; = p.Q1012* on NM_002973.4) | Nonsense Mutation (SNP) | VAF 29/93 reads (31%) | catalogued as COSV101112881; called by muse, mutect2, varscan2
- BCKDHB | c.392G>C p.G131A | Missense Mutation (SNP) | VAF 63/315 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.409); catalogued as rs774472182; called by muse, mutect2, varscan2
- C3orf20 | c.1197del p.T400Hfs*36 | Frame Shift Del (DEL) | VAF 32/154 reads (21%) | catalogued as COSV99514661; called by mutect2, pindel, varscan2
- CACNA2D3 | c.1968C>A p.C656* | Nonsense Mutation (SNP) | VAF 50/189 reads (26%) | catalogued as rs1553905045; called by muse, mutect2, varscan2
- CALN1 | c.644G>A p.R215Q (on ENST00000329008 / NM_001017440.3; = p.R257Q on NM_031468.4) | Missense Mutation (SNP) | VAF 34/151 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs370771019, COSV61142530; called by muse, mutect2, varscan2
- CCDC197 | c.263C>A p.A88D | Missense Mutation (SNP) | VAF 25/150 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs1358359345; called by muse, mutect2, varscan2
- CCDC33 | c.1097G>A p.R366K | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as COSV58355253; called by muse, mutect2, varscan2
- COL11A1 | c.2536C>A p.P846T | Missense Mutation (SNP) | VAF 36/159 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs750390186, COSV100615895; called by muse, mutect2, varscan2
- COL3A1 | c.4151G>T p.G1384V | Missense Mutation (SNP) | VAF 32/189 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100482444; called by muse, mutect2, varscan2
- CORO7 | c.2245G>C p.G749R | Missense Mutation (SNP) | VAF 28/188 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.342); catalogued as COSV99227253; called by muse, mutect2, varscan2
- CPA6 | c.590C>A p.A197E | Missense Mutation (SNP) | VAF 29/210 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754644677; called by muse, mutect2, varscan2
- CROCC2 | c.890G>T p.G297V | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as COSV70369342; called by muse, mutect2, varscan2
- CSMD1 | c.9122C>T p.P3041L (on ENST00000520002; = p.P3040L on NM_033225.6) | Missense Mutation (SNP) | VAF 31/132 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1467515940; called by muse, mutect2, varscan2
- CTAG2 | c.73G>A p.D25N | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.009); catalogued as rs1557241879, COSV55994574; called by muse, varscan2
- CTSA | c.172G>T p.G58C | Missense Mutation (SNP) | VAF 64/326 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.788); catalogued as COSV51942046; called by muse, mutect2, varscan2
- DCAF12L1 | c.720del p.V241Yfs*72 | Frame Shift Del (DEL) | VAF 36/117 reads (31%) | catalogued as COSV64421109, COSV64422957; called by mutect2, pindel, varscan2
- DLGAP2 | c.1186C>A p.H396N | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.163); catalogued as COSV70101243; called by muse, mutect2, varscan2
- DNAAF1 | c.872C>A p.A291E | Missense Mutation (SNP) | VAF 74/430 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57576563; called by muse, mutect2, varscan2
- DNAH9 | c.1828G>T p.G610C | Missense Mutation (SNP) | VAF 46/217 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.087); catalogued as COSV99304140, COSV99304908; called by muse, mutect2, varscan2
- ERBB4 | c.2245G>T p.A749S | Missense Mutation (SNP) | VAF 47/230 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs745709151; called by muse, mutect2, varscan2
- ERICH1 | c.1204G>A p.E402K | Missense Mutation (SNP) | VAF 87/351 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.061); catalogued as rs1310275847; called by muse, mutect2, varscan2
- EVPLL | c.427G>A p.G143R | Missense Mutation (SNP) | VAF 44/220 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs781611618; called by muse, mutect2, varscan2
- EXOC3L4 | c.1999C>G p.L667V | Missense Mutation (SNP) | VAF 31/142 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs760213756; called by muse, mutect2, varscan2
- EXOC5 | c.1312G>T p.D438Y | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs1476985336; called by muse, mutect2, varscan2
- EYS | c.2494C>A p.Q832K | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV101009122; called by muse, mutect2, varscan2
- FAM107B | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 131/391 reads (34%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.006); catalogued as rs1413704060, COSV51692424; called by muse, mutect2, varscan2
- FAM149A | c.1184C>T p.S395L (on ENST00000356371 / NM_001367768.2; = p.S104L on NM_015398.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/267 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.188); catalogued as rs771526600; called by muse, mutect2, varscan2
- FAM170A | c.583G>C p.E195Q | Missense Mutation (SNP) | VAF 27/149 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as COSV58925330; called by muse, mutect2, varscan2
- FASLG | c.152C>G p.P51R | Missense Mutation (SNP) | VAF 184/435 reads (42%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.763); catalogued as COSV60680147; called by muse, mutect2, varscan2
- FAT2 | c.677G>A p.R226H | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777551798, COSV55816959; called by muse, mutect2, varscan2
- GABRG1 | c.1273G>T p.G425* | Nonsense Mutation (SNP) | VAF 60/384 reads (16%) | catalogued as rs200863268; called by muse, mutect2, varscan2
- GIGYF2 | c.278C>A p.S93Y | Missense Mutation (SNP) | VAF 22/159 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65249633; called by muse, mutect2, varscan2
- GPR85 | c.1040G>T p.R347M | Missense Mutation (SNP) | VAF 41/166 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV51784334; called by muse, mutect2, varscan2
- GRK3 | c.1093G>A p.G365R | Missense Mutation (SNP) | VAF 45/205 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs953906647; called by muse, mutect2, varscan2
- HMGCR | c.917C>T p.S306F | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.342); catalogued as COSV55317986; called by muse, mutect2, varscan2
- IL17RD | c.1518G>T p.Q506H | Missense Mutation (SNP) | VAF 46/184 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.88); catalogued as rs769391464; called by muse, mutect2, varscan2
- IQCA1 | c.1366G>A p.D456N | Missense Mutation (SNP) | VAF 56/326 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.078); catalogued as rs771026031; called by muse, mutect2, varscan2
- IRX2 | c.1075G>T p.A359S | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT tolerated (0.94); PolyPhen benign (0.007); catalogued as COSV57410386; called by muse, mutect2, varscan2
- JUP | c.1804C>T p.R602C | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs199511559, COSV60277833; ClinVar: uncertain significance; called by mutect2, varscan2
- KCNK15 | c.769G>T p.A257S | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT tolerated (0.5); PolyPhen benign (0.12); catalogued as COSV65719148, COSV65720082; called by muse, mutect2
- KCNMA1 | c.1539G>T p.K513N | Missense Mutation (SNP) | VAF 78/436 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54231854; called by muse, mutect2, varscan2
- KEAP1 | c.994G>T p.G332C | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1208201314, COSV50405151, COSV50635595; called by muse, mutect2, varscan2
- KIF21B | c.104C>T p.P35L | Missense Mutation (SNP) | VAF 85/350 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.704); catalogued as rs565712809; called by muse, mutect2, varscan2
- KLHDC7A | c.1285C>A p.R429S | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.16); catalogued as COSV68770114; called by muse, mutect2, varscan2
- KLHL4 | c.1513G>T p.V505L | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.36); PolyPhen benign (0.292); catalogued as COSV64147229; called by muse, mutect2, varscan2
- KRT33B | c.202G>T p.A68S | Missense Mutation (SNP) | VAF 111/515 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99290607; called by muse, mutect2, varscan2
- KRTAP19-3 | c.221G>T p.G74V | Missense Mutation (SNP) | VAF 38/214 reads (18%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.304); catalogued as COSV61854593, COSV61855062; called by muse, mutect2, varscan2
- KRTAP19-3 | c.220G>T p.G74* | Nonsense Mutation (SNP) | VAF 38/217 reads (18%) | catalogued as COSV100477614; called by muse, mutect2, varscan2
- LAPTM4A | c.398A>G p.Y133C | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1030785990; called by muse, mutect2, varscan2
- LBP | c.706C>A p.P236T | Missense Mutation (SNP) | VAF 37/231 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99461196; called by muse, mutect2, varscan2
- LILRB4 | c.934G>T p.G312W | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV99553745; called by muse, mutect2, varscan2
- LMOD3 | c.1483C>G p.R495G | Missense Mutation (SNP) | VAF 49/170 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); catalogued as COSV101341961; called by muse, mutect2, varscan2
- LRP1B | c.1370G>T p.W457L | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV67195948; called by muse, mutect2
- LRP2 | c.9913C>A p.R3305S | Missense Mutation (SNP) | VAF 74/416 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as COSV104378304; called by muse, mutect2, varscan2
- LRP2 | c.4196C>G p.S1399C | Missense Mutation (SNP) | VAF 61/267 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.657); catalogued as COSV99788920; called by muse, mutect2, varscan2
- MAGI2 | c.2719C>A p.P907T | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.065); catalogued as COSV100833357; called by muse, mutect2, varscan2
- MAP1A | c.5090G>A p.W1697* | Nonsense Mutation (SNP) | VAF 27/143 reads (19%) | catalogued as rs1484275804; called by muse, mutect2, varscan2
- MAP4K2 | c.2326C>G p.Q776E | Missense Mutation (SNP) | VAF 81/361 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.973); catalogued as COSV99581191; called by muse, mutect2, varscan2
- MARCHF4 | c.79C>A p.P27T | Missense Mutation (SNP) | VAF 32/173 reads (18%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.001); catalogued as rs769269823; called by muse, mutect2, varscan2
- MMP7 | c.524C>T p.T175M | Missense Mutation (SNP) | VAF 52/265 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as rs542899524, COSV52772100; called by muse, mutect2, varscan2
- NALCN | c.481G>C p.E161Q | Missense Mutation (SNP) | VAF 54/262 reads (21%) | SIFT tolerated (0.58); PolyPhen benign (0.042); catalogued as COSV51943916; called by muse, mutect2, varscan2
- NEB | c.4850G>A p.G1617D | Missense Mutation (SNP) | VAF 80/430 reads (19%) | SIFT tolerated (1); PolyPhen probably damaging (0.999); catalogued as rs764120498; called by muse, mutect2, varscan2
- NLRP3 | c.922G>T p.A308S | Missense Mutation (SNP) | VAF 86/356 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.262); catalogued as COSV100275567; called by mutect2, varscan2
- NLRP3 | c.1301C>G p.S434C | Missense Mutation (SNP) | VAF 28/349 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV60224249; called by muse, mutect2
- NTRK3 | c.2105G>A p.R702K | Missense Mutation (SNP) | VAF 58/310 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62320161; called by muse, mutect2, varscan2
- NWD1 | c.2143C>T p.Q715* | Nonsense Mutation (SNP) | VAF 17/73 reads (23%) | catalogued as rs1254507084; called by muse, mutect2, varscan2
- OR10G7 | c.107C>A p.T36N | Missense Mutation (SNP) | VAF 22/177 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); catalogued as COSV100389770; called by muse, mutect2, varscan2
- OR4K2 | c.550G>C p.V184L | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.521); catalogued as rs1232190470, COSV53849925; called by muse, mutect2, varscan2
- OR4M1 | c.235C>A p.P79T | Missense Mutation (SNP) | VAF 27/142 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100270954, COSV60061572; called by muse, mutect2, varscan2
- OR5B12 | c.830C>A p.A277D | Missense Mutation (SNP) | VAF 49/266 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.281); catalogued as COSV56904858, COSV56906633; called by muse, mutect2, varscan2
- OR5T1 | c.488C>A p.A163D | Missense Mutation (SNP) | VAF 38/164 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.127); catalogued as COSV57302001; called by muse, mutect2
- OR8H2 | c.800C>A p.S267Y | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as COSV100542553, COSV57945149; called by muse, mutect2, varscan2
- PAN3 | c.1655G>T p.R552L | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as COSV56707925; called by muse, mutect2, varscan2
- PASD1 | c.982C>A p.P328T | Missense Mutation (SNP) | VAF 99/268 reads (37%) | SIFT tolerated (0.56); PolyPhen benign (0.181); catalogued as rs756009277; called by mutect2, varscan2
- PCDH15 | c.4313C>A p.P1438Q | Missense Mutation (SNP) | VAF 91/270 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.775); catalogued as COSV57274006; called by muse, varscan2
- PCDHB2 | c.295G>A p.G99S | Missense Mutation (SNP) | VAF 35/213 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.781); catalogued as rs1554271156, COSV52030440; called by muse, mutect2, varscan2
- PHKB | c.1741G>T p.D581Y | Missense Mutation (SNP) | VAF 45/372 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54516599; called by muse, mutect2, varscan2
- PKD1L1 | c.1174G>T p.E392* | Nonsense Mutation (SNP) | VAF 47/289 reads (16%) | catalogued as COSV99218449; called by muse, mutect2, varscan2
- PLCZ1 | c.203C>A p.T68K | Missense Mutation (SNP) | VAF 35/155 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as COSV56849845; called by muse, mutect2, varscan2
- PPP1R3A | c.257C>T p.P86L | Missense Mutation (SNP) | VAF 59/251 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1179318748, COSV52878523; called by muse, mutect2, varscan2
- PPP1R3A | c.256C>A p.P86T | Missense Mutation (SNP) | VAF 57/245 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52883437; called by muse, mutect2, varscan2
- PRLHR | c.130G>T p.A44S | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs139320666; called by muse, mutect2, varscan2
- PSD3 | c.1295G>T p.G432V | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.05); catalogued as rs369499870; called by muse, mutect2, varscan2
- PSG5 | c.88del p.L30Cfs*43 | Frame Shift Del (DEL) | VAF 19/86 reads (22%) | catalogued as rs751703914; called by mutect2, pindel, varscan2
- PTPRD | c.5247G>T p.M1749I | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.133); catalogued as COSV100646130; called by muse, varscan2
- PTPRF | c.3524G>T p.R1175L | Missense Mutation (SNP) | VAF 61/170 reads (36%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.844); catalogued as COSV100741000, COSV63446499; called by muse, mutect2, varscan2
- PTPRH | c.3225C>A p.C1075* | Nonsense Mutation (SNP) | VAF 39/193 reads (20%) | catalogued as COSV54748698; called by muse, mutect2, varscan2
- RAD51D | c.777G>T p.R259S | Missense Mutation (SNP) | VAF 93/428 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.009); catalogued as rs746648511; called by muse, mutect2, varscan2
- RBM24 | c.51del p.L18Cfs*66 | Frame Shift Del (DEL) | VAF 34/138 reads (25%) | catalogued as rs1561732132; called by mutect2, pindel, varscan2
- RFK | c.52C>T p.R18C | Missense Mutation (SNP) | VAF 29/131 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs985045404; called by muse, mutect2, varscan2
- RIMS2 | c.2116C>G p.R706G (on ENST00000666250 / NM_001348490.2; = p.R514G on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/166 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV51665289, COSV51728222; called by muse, mutect2, varscan2
- RXRG | c.175G>T p.V59L | Missense Mutation (SNP) | VAF 40/316 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs143885966; called by muse, mutect2
- SAE1 | c.704G>C p.R235P | Missense Mutation (SNP) | VAF 43/201 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.229); catalogued as COSV54298820; called by muse, mutect2, varscan2
- SEMA3G | c.1537G>A p.G513S | Missense Mutation (SNP) | VAF 48/151 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.348); catalogued as rs1163188981, COSV51597326; called by muse, mutect2, varscan2
- SESN2 | c.1013G>A p.R338Q | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs368191829; called by muse, mutect2
- SLC9B2 | c.397G>A p.G133R | Missense Mutation (SNP) | VAF 43/230 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0.045); catalogued as rs941637378; called by muse, mutect2, varscan2
- SLCO6A1 | c.1520G>T p.R507I | Missense Mutation (SNP) | VAF 43/241 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.326); catalogued as COSV65811324; called by muse, mutect2, varscan2
- SMARCA4 | c.4852C>T p.R1618* | Nonsense Mutation (SNP) | VAF 29/105 reads (28%) | catalogued as rs1306144699, COSV60797219; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMG1 | c.2687G>T p.R896L | Missense Mutation (SNP) | VAF 60/328 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1052925102; called by muse, mutect2, varscan2
- SMG5 | c.922G>T p.E308* | Nonsense Mutation (SNP) | VAF 34/186 reads (18%) | catalogued as rs1270762500; called by muse, mutect2, varscan2
- SORCS1 | c.244C>A p.P82T | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.021); catalogued as COSV53895252; called by muse, mutect2
- SPHKAP | c.3449A>G p.Y1150C | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60896625; called by muse, mutect2, varscan2
- SPHKAP | c.3091G>T p.V1031F | Missense Mutation (SNP) | VAF 19/140 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.125); catalogued as COSV60890903; called by muse, mutect2, varscan2
- SULF2 | c.111G>T p.R37S | Missense Mutation (SNP) | VAF 29/171 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.606); catalogued as COSV99053814; called by muse, mutect2, varscan2
- TEX55 | c.220G>T p.G74* | Nonsense Mutation (SNP) | VAF 42/207 reads (20%) | catalogued as COSV99817633; called by mutect2, varscan2
- TG | c.1049G>A p.R350Q | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.081); catalogued as rs113998044; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TNKS | c.3736C>T p.H1246Y | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV60057419; called by muse, varscan2
- TRIM24 | c.130G>T p.G44C | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as rs751340675, COSV58969201; called by muse, mutect2, varscan2
- TRIM77 | c.639G>T p.K213N | Missense Mutation (SNP) | VAF 35/200 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.266); catalogued as COSV68066002; called by muse, mutect2, varscan2
- TSHZ3 | c.2297del p.P766Rfs*25 | Frame Shift Del (DEL) | VAF 7/32 reads (22%) | catalogued as COSV53671958; called by mutect2, pindel, varscan2
- TSPOAP1 | c.3662G>T p.G1221V | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); catalogued as COSV52111058; called by muse, mutect2, varscan2
- UBR5 | c.7111G>A p.D2371N | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.488); catalogued as rs1386266792; called by muse, mutect2, varscan2
- VAT1L | c.883-1G>C p.X295_splice | Splice Site (SNP) | VAF 62/303 reads (20%) | catalogued as rs770254820; called by muse, mutect2, varscan2
- YBX3 | c.326G>A p.R109Q | Missense Mutation (SNP) | VAF 39/216 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.605); catalogued as COSV54385681; called by muse, mutect2, varscan2
- ZFHX4 | c.2225C>A p.S742Y | Missense Mutation (SNP) | VAF 17/137 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.323); catalogued as COSV50665148; called by muse, mutect2, varscan2
- ZNF804A | c.1201C>A p.P401T | Missense Mutation (SNP) | VAF 38/199 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as COSV100167703, COSV56448862; called by muse, mutect2, varscan2
- ABCA13 | c.7162G>C p.V2388L | Missense Mutation (SNP) | VAF 51/241 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- ACOT4 | c.194C>A p.A65E | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- ANKRD30BL | c.709G>T p.A237S | Missense Mutation (SNP) | VAF 65/379 reads (17%) | SIFT tolerated (0.62); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- ANKRD31 | c.4887_4893del p.G1630Qfs*12 | Frame Shift Del (DEL) | VAF 29/171 reads (17%) | called by mutect2, pindel, varscan2
- ANO2 | c.110del p.P37Qfs*126 (on ENST00000356134 / NM_001278597.3; = p.P41Qfs*126 on NM_001278596.3) | Frame Shift Del (DEL) | VAF 19/107 reads (18%) | called by mutect2, pindel, varscan2
- API5 | c.190A>T p.I64F | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- APPBP2 | c.1069G>A p.A357T | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- ARMC4 | c.3107T>A p.L1036H | Missense Mutation (SNP) | VAF 84/267 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- ARNT | c.209A>T p.D70V | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ASB14 | c.302T>C p.I101T (on ENST00000389601; = p.I100T on NM_001142733.3) | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- ASCC3 | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ATP2B3 | c.461G>A p.W154* | Nonsense Mutation (SNP) | VAF 43/74 reads (58%) | called by muse, mutect2, varscan2
- BBX | c.2770G>T p.G924* (on ENST00000325805 / NM_001142568.3; = p.G894* on NM_020235.7) | Nonsense Mutation (SNP) | VAF 27/130 reads (21%) | called by muse, mutect2, varscan2
- BMP1 | c.2713G>T p.V905L | Missense Mutation (SNP) | VAF 75/396 reads (19%) | SIFT tolerated (0.58); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- BRWD3 | c.4549G>C p.G1517R | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BTLA | c.544C>A p.Q182K | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- BTLA | c.543C>A p.H181Q | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- C20orf173 | c.209C>A p.P70H (on ENST00000246199; = p.P123H on NM_001145350.2) | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- C6 | c.132G>T p.Q44H | Missense Mutation (SNP) | VAF 61/315 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CACNA1E | c.6491C>A p.P2164Q (on ENST00000367573 / NM_001205293.3; = p.P2121Q on NM_000721.4) | Missense Mutation (SNP) | VAF 42/254 reads (17%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- CACNB2 | c.1896T>G p.D632E (on ENST00000324631 / NM_201596.3; = p.D577E on NM_000724.4) | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT tolerated, low confidence (0.43); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CAMK4 | c.581A>G p.H194R | Missense Mutation (SNP) | VAF 37/197 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- CARMIL3 | c.4076G>C p.R1359P | Missense Mutation (SNP) | VAF 39/226 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- CCDC168 | c.14627A>T p.Q4876L | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.209); called by muse, mutect2
- CCDC74A | c.569C>A p.S190Y | Missense Mutation (SNP) | VAF 24/273 reads (9%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.991); called by muse, mutect2
- CDC42BPG | c.1147C>T p.H383Y | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CES4A | c.20G>T p.W7L | Missense Mutation (SNP) | VAF 29/163 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CFAP47 | c.2390A>T p.Q797L | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- CFAP65 | c.2917C>A p.P973T | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- CHL1 | c.1696G>A p.D566N (on ENST00000397491 / NM_001253387.1; = p.D582N on NM_006614.4) | Missense Mutation (SNP) | VAF 34/211 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CHML | c.1688G>T p.S563I | Missense Mutation (SNP) | VAF 46/138 reads (33%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- CNIH3 | c.408G>C p.W136C | Missense Mutation (SNP) | VAF 89/363 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CNTNAP5 | c.3548C>A p.A1183D | Missense Mutation (SNP) | VAF 42/194 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- COG6 | c.847G>A p.D283N | Missense Mutation (SNP) | VAF 93/421 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- COL11A1 | c.2008G>T p.G670C | Missense Mutation (SNP) | VAF 27/142 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL6A3 | c.3326G>C p.G1109A | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL6A5 | c.3707G>T p.C1236F | Missense Mutation (SNP) | VAF 78/396 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COPG1 | c.2015A>T p.Q672L | Missense Mutation (SNP) | VAF 48/195 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- CPZ | c.1085A>T p.K362M (on ENST00000360986 / NM_001014447.3; = p.K351M on NM_003652.3) | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- CRB1 | c.1436T>A p.L479Q | Missense Mutation (SNP) | VAF 55/356 reads (15%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- CRYBG3 | c.1858A>G p.I620V | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- CTNNA2 | c.2629del p.V877Sfs*4 (on ENST00000402739 / NM_001282597.3; = p.V829Sfs*4 on NM_004389.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 21/127 reads (17%) | called by mutect2, pindel, varscan2
- CYP2W1 | c.269C>A p.A90E | Missense Mutation (SNP) | VAF 26/172 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); called by muse, mutect2, varscan2
- DCC | c.4055C>A p.P1352Q | Missense Mutation (SNP) | VAF 132/602 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- DLG2 | c.2107G>C p.D703H | Missense Mutation (SNP) | VAF 54/210 reads (26%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.92); called by muse, varscan2
- DMGDH | c.919C>A p.L307I | Missense Mutation (SNP) | VAF 47/244 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- DMRT1 | c.527C>A p.T176N | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- DOCK2 | c.709G>A p.D237N | Missense Mutation (SNP) | VAF 31/191 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DOCK2 | c.4524G>C p.K1508N | Missense Mutation (SNP) | VAF 40/149 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- DOK7 | c.169C>A p.L57M | Missense Mutation (SNP) | VAF 45/150 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- DSC3 | c.2426C>A p.T809K | Missense Mutation (SNP) | VAF 44/178 reads (25%) | SIFT tolerated (0.67); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- DYNC2H1 | c.134A>G p.D45G | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- DZANK1 | c.1802A>T p.Q601L (on ENST00000262547 / NM_001099407.1; = p.Q408L on NM_018152.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DZIP3 | c.1877del p.P626Lfs*57 | Frame Shift Del (DEL) | VAF 15/103 reads (15%) | called by mutect2, pindel, varscan2
- ELOVL7 | c.530A>G p.N177S | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- F10 | c.49C>T p.L17F | Missense Mutation (SNP) | VAF 77/384 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- FAM124B | c.1047C>A p.N349K | Missense Mutation (SNP) | VAF 103/488 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- FAM171B | c.1372G>T p.D458Y | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- FAM47A | c.335T>C p.L112P | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- FAM81A | c.1068G>T p.K356N | Missense Mutation (SNP) | VAF 43/198 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FAM83A | c.1168C>A p.H390N | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- FAT3 | c.10431C>A p.H3477Q | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.047); called by muse, varscan2
- FBXW10 | c.829T>A p.F277I | Missense Mutation (SNP) | VAF 32/273 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- FERMT2 | c.1208C>T p.S403F | Missense Mutation (SNP) | VAF 38/205 reads (19%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- FHAD1 | c.2435C>G p.A812G | Missense Mutation (SNP) | VAF 41/180 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- FLG | c.4813G>T p.E1605* | Nonsense Mutation (SNP) | VAF 65/463 reads (14%) | called by muse, mutect2, varscan2
- FNIP2 | c.2831G>T p.G944V | Missense Mutation (SNP) | VAF 23/137 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- FRMPD1 | c.2363G>A p.R788K | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- GAB4 | c.998T>A p.M333K | Missense Mutation (SNP) | VAF 32/229 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- GABRA4 | c.50G>T p.S17I | Missense Mutation (SNP) | VAF 33/281 reads (12%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- GHRHR | c.146C>T p.P49L | Missense Mutation (SNP) | VAF 93/471 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- GPR31 | c.352C>T p.H118Y | Missense Mutation (SNP) | VAF 39/181 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- GRM6 | c.504G>T p.A168= | Splice Region (SNP) | VAF 29/147 reads (20%) | called by muse, mutect2, varscan2
- GSG1L2 | c.697C>A p.L233M | Missense Mutation (SNP) | VAF 56/293 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- GUCY1A2 | c.1389T>A p.D463E | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- HAO1 | c.908C>A p.A303D | Missense Mutation (SNP) | VAF 54/309 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HDC | c.788G>T p.C263F | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- HDC | c.788-1G>T p.X263_splice | Splice Site (SNP) | VAF 17/102 reads (17%) | called by muse, varscan2
- HPD | c.241+8G>T | Splice Region (SNP) | VAF 55/247 reads (22%) | called by muse, mutect2, varscan2
- HRH2 | c.641A>G p.K214R | Missense Mutation (SNP) | VAF 69/385 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- HSPA13 | c.1147G>T p.V383L | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- HTR3B | c.955A>T p.K319* | Nonsense Mutation (SNP) | VAF 33/108 reads (31%) | called by muse, mutect2, varscan2
- IGHV4-28 | c.26T>A p.L9Q | Missense Mutation (SNP) | VAF 31/634 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.147); called by muse, mutect2
- INSL4 | c.208A>G p.T70A | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.006); called by muse, mutect2
- INSYN2B | c.407del p.G136Vfs*16 | Frame Shift Del (DEL) | VAF 16/96 reads (17%) | called by mutect2, pindel, varscan2
- ITGA2B | c.643G>C p.G215R | Missense Mutation (SNP) | VAF 94/463 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ITGAV | c.1534G>T p.D512Y | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- ITPR1 | c.812C>T p.S271L | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- KAZN | c.1276G>T p.E426* | Nonsense Mutation (SNP) | VAF 69/207 reads (33%) | called by muse, mutect2, varscan2
- KCNA2 | c.1280C>A p.A427D | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- KCNH1 | c.1372A>T p.M458L (on ENST00000271751 / NM_172362.3; = p.M431L on NM_002238.4) | Missense Mutation (SNP) | VAF 47/337 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- KIAA0930 | c.656G>T p.R219L (on ENST00000336156 / NM_001009880.2; = p.R224L on NM_015264.2) | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.716); called by muse, mutect2, varscan2
- KIAA1549L | c.2237G>T p.R746M (on ENST00000321505; = p.R1043M on NM_012194.3) | Missense Mutation (SNP) | VAF 66/326 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- KIF16B | c.763G>T p.G255* | Nonsense Mutation (SNP) | VAF 63/383 reads (16%) | called by muse, mutect2, varscan2
- KRT18 | c.1172+8G>T | Splice Region (SNP) | VAF 88/409 reads (22%) | called by muse, mutect2, varscan2
- LACRT | c.167C>A p.T56K | Missense Mutation (SNP) | VAF 65/283 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- LPA | c.4245G>C p.M1415I | Missense Mutation (SNP) | VAF 57/336 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.361); called by muse, mutect2
- LPAR2 | c.605T>A p.L202Q | Missense Mutation (SNP) | VAF 44/178 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- LPAR4 | c.89C>A p.T30N | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.81); PolyPhen benign (0.001); called by muse, varscan2
- LRP1 | c.8771G>T p.C2924F | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRRC71 | c.974G>A p.G325E | Missense Mutation (SNP) | VAF 62/219 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- LRRIQ3 | c.1210A>T p.M404L | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2, varscan2
- LYST | c.9557A>G p.Y3186C | Missense Mutation (SNP) | VAF 41/249 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MALRD1 | c.4602G>T p.Q1534H | Missense Mutation (SNP) | VAF 48/316 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- MALRD1 | c.4603G>C p.A1535P | Missense Mutation (SNP) | VAF 49/311 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- MAP1A | c.3116T>A p.V1039E | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- MAPK8IP2 | c.2373G>T p.E791D | Missense Mutation (SNP) | VAF 59/248 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- MED12L | c.1303G>T p.G435C | Missense Mutation (SNP) | VAF 46/238 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- MIPEP | c.217G>A p.A73T | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT tolerated (0.92); PolyPhen benign (0); called by muse, mutect2, varscan2
- MS4A10 | c.185C>G p.A62G | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.135); called by mutect2, varscan2
- MUC6 | c.2240T>A p.I747N | Missense Mutation (SNP) | VAF 43/211 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MYH13 | c.5671G>T p.E1891* | Nonsense Mutation (SNP) | VAF 31/150 reads (21%) | called by muse, mutect2, varscan2
- MYOC | c.901T>A p.Y301N | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NAV3 | c.3907G>A p.G1303R | Missense Mutation (SNP) | VAF 130/643 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NCKAP5 | c.3967C>T p.P1323S | Missense Mutation (SNP) | VAF 35/153 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- NDUFS1 | c.1110G>T p.E370D | Missense Mutation (SNP) | VAF 55/276 reads (20%) | SIFT tolerated (1); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- NECTIN4 | c.1102G>T p.V368L | Missense Mutation (SNP) | VAF 146/561 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.014); called by mutect2, varscan2
- NEFM | c.1837G>T p.A613S | Missense Mutation (SNP) | VAF 78/366 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- NELL2 | c.1908C>G p.C636W | Missense Mutation (SNP) | VAF 68/368 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- NEUROG1 | c.596C>A p.P199H | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NGF | c.421G>T p.V141L | Missense Mutation (SNP) | VAF 43/152 reads (28%) | SIFT tolerated (0.56); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- NLRP3 | c.2005G>A p.E669K | Missense Mutation (SNP) | VAF 41/308 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NOBOX | c.1469+1del p.X490_splice | Splice Site (DEL) | VAF 24/160 reads (15%) | called by pindel, varscan2
- NRXN3 | c.1839C>A p.D613E (on ENST00000335750 / NM_001330195.2; = p.D240E on NM_004796.6) | Missense Mutation (SNP) | VAF 56/288 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- NT5DC1 | c.185G>T p.C62F | Missense Mutation (SNP) | VAF 50/208 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NUBPL | c.295A>T p.K99* | Nonsense Mutation (SNP) | VAF 44/237 reads (19%) | called by muse, mutect2, varscan2
- NYAP1 | c.698G>T p.G233V | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- OCA2 | c.111G>C p.R37S | Missense Mutation (SNP) | VAF 96/509 reads (19%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- OCA2 | c.110G>T p.R37M | Missense Mutation (SNP) | VAF 96/512 reads (19%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- OR10G9 | c.107C>A p.T36N | Missense Mutation (SNP) | VAF 34/470 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); called by muse, mutect2
- OR10K2 | c.368A>G p.Y123C | Missense Mutation (SNP) | VAF 53/346 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- OR12D2 | c.463C>G p.L155V | Missense Mutation (SNP) | VAF 60/274 reads (22%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- OR14K1 | c.286G>T p.V96L | Missense Mutation (SNP) | VAF 69/501 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- OR2AJ1 | c.847C>A p.P283T | Missense Mutation (SNP) | VAF 30/328 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- OR4K14 | c.127C>G p.L43V | Missense Mutation (SNP) | VAF 55/282 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- OR4M1 | c.236C>G p.P79R | Missense Mutation (SNP) | VAF 27/144 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR8D2 | c.363C>A p.D121E | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- OSTM1 | c.615+1G>T p.X205_splice | Splice Site (SNP) | VAF 15/99 reads (15%) | called by muse, mutect2, varscan2
- OTOF | c.2399G>C p.R800T (on ENST00000272371 / NM_194248.3; = p.R53T on NM_004802.4) | Missense Mutation (SNP) | VAF 74/313 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- OVCH1 | c.2593C>A p.L865M | Missense Mutation (SNP) | VAF 57/273 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- OVCH1 | c.2351G>T p.W784L | Missense Mutation (SNP) | VAF 29/215 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- OVCH1 | c.2350T>C p.W784R | Missense Mutation (SNP) | VAF 30/216 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- P2RY8 | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 35/185 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- PARP10 | c.1189C>A p.Q397K | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.145); called by muse, mutect2
- PCDH15 | c.4425C>A p.D1475E | Missense Mutation (SNP) | VAF 56/173 reads (32%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PCDH15 | c.491C>A p.T164N | Missense Mutation (SNP) | VAF 87/291 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDHGA9 | c.416A>G p.E139G | Missense Mutation (SNP) | VAF 57/236 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- PCDHGB6 | c.38C>G p.P13R | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- PCDHGB6 | c.730A>T p.R244* | Nonsense Mutation (SNP) | VAF 28/112 reads (25%) | called by muse, mutect2, varscan2
- PCDHGC3 | c.792del p.Q265Kfs*33 | Frame Shift Del (DEL) | VAF 16/119 reads (13%) | called by mutect2, pindel, varscan2
- PEAR1 | c.688C>A p.P230T | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- PLEC | c.5630A>T p.Q1877L (on ENST00000322810 / NM_201380.4; = p.Q1767L on NM_000445.5) | Missense Mutation (SNP) | VAF 24/144 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- POTEB3 | c.433A>T p.R145* | Nonsense Mutation (SNP) | VAF 7/32 reads (22%) | called by mutect2, varscan2
- POTEH | c.1052G>C p.C351S | Missense Mutation (SNP) | VAF 34/857 reads (4%) | SIFT tolerated (0.46); PolyPhen benign (0.245); called by muse, mutect2
- PPM1A | c.1015A>T p.S339C | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.457); called by muse, mutect2, varscan2
- PPP6R1 | c.61G>A p.D21N | Missense Mutation (SNP) | VAF 54/174 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- PRAMEF2 | c.870C>A p.C290* | Nonsense Mutation (SNP) | VAF 30/98 reads (31%) | called by muse, varscan2
- PRAMEF4 | c.1379G>A p.C460Y | Missense Mutation (SNP) | VAF 46/279 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.023); called by muse, varscan2
- PRR5L | c.346T>A p.C116S | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- PTPRC | c.940G>T p.V314F | Missense Mutation (SNP) | VAF 31/174 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- R3HDM1 | c.323T>C p.L108S | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RAPGEF4 | c.2528T>A p.L843Q | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RBBP6 | c.2458G>T p.D820Y | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- RBBP8NL | c.1741A>T p.S581C | Missense Mutation (SNP) | VAF 40/178 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- RELB | c.772C>T p.H258Y | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.471); called by muse, mutect2, varscan2
- RFTN2 | c.362C>A p.P121Q | Missense Mutation (SNP) | VAF 69/337 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- RFX4 | c.437C>A p.S146Y (on ENST00000392842 / NM_213594.3; = p.S52Y on NM_032491.6) | Missense Mutation (SNP) | VAF 39/289 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- RXFP3 | c.868C>A p.L290M | Missense Mutation (SNP) | VAF 30/214 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RYR3 | c.9514C>A p.L3172M (on ENST00000389232; = p.L3173M on NM_001036.6) | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- RYR3 | c.10477G>T p.A3493S (on ENST00000389232; = p.A3494S on NM_001036.6) | Missense Mutation (SNP) | VAF 56/291 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- SACS | c.2267C>T p.P756L | Missense Mutation (SNP) | VAF 36/206 reads (17%) | SIFT tolerated (0.81); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SCN4A | c.2579A>C p.E860A | Missense Mutation (SNP) | VAF 29/149 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SERPINB2 | c.1072G>T p.A358S | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT tolerated (0.98); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- SESN2 | c.1015G>A p.A339T | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.932); called by muse, mutect2
- SH3PXD2A | c.807G>T p.E269D (on ENST00000369774 / NM_001365079.1; = p.E241D on NM_014631.2) | Missense Mutation (SNP) | VAF 53/134 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SHANK1 | c.1831G>T p.V611L | Missense Mutation (SNP) | VAF 41/207 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- SIT1 | c.157C>A p.L53M | Missense Mutation (SNP) | VAF 44/158 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- SLC12A1 | c.1988C>A p.A663D | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- SLC13A5 | c.135G>T p.M45I | Missense Mutation (SNP) | VAF 27/150 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- SLC15A5 | c.985G>T p.G329* | Nonsense Mutation (SNP) | VAF 20/94 reads (21%) | called by muse, mutect2, varscan2
- SLC22A12 | c.943C>A p.L315M | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC25A44 | c.626-8G>T | Splice Region (SNP) | VAF 18/162 reads (11%) | called by muse, mutect2, varscan2
- SLC6A18 | c.590G>T p.C197F | Missense Mutation (SNP) | VAF 49/289 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SLC6A5 | c.2014C>G p.Q672E | Missense Mutation (SNP) | VAF 54/307 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- SLC8A2 | c.2171A>G p.Y724C | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SORCS1 | c.465G>T p.M155I | Missense Mutation (SNP) | VAF 64/220 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SOX7 | c.198G>C p.Q66H | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, varscan2
- SP9 | c.11C>A p.S4Y | Missense Mutation (SNP) | VAF 44/215 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- SPIRE2 | c.643G>T p.E215* | Nonsense Mutation (SNP) | VAF 12/80 reads (15%) | called by muse, mutect2, varscan2
- ST3GAL4 | c.28C>A p.L10M | Missense Mutation (SNP) | VAF 49/253 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- STK11 | c.443dup p.V150Sfs*13 | Frame Shift Ins (INS) | VAF 34/158 reads (22%) | called by pindel, varscan2
- STK32A | c.618G>C p.W206C | Missense Mutation (SNP) | VAF 52/336 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TAAR6 | c.547G>T p.A183S | Missense Mutation (SNP) | VAF 37/222 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- TAF1L | c.4885C>A p.H1629N | Missense Mutation (SNP) | VAF 43/163 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.752); called by muse, varscan2
- TAS2R41 | c.474_475insC p.F159Lfs*4 | Frame Shift Ins (INS) | VAF 59/274 reads (22%) | called by mutect2, pindel, varscan2
- TCERG1L | c.1660G>T p.V554F | Missense Mutation (SNP) | VAF 42/252 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- TCERG1L | c.914A>T p.Q305L | Missense Mutation (SNP) | VAF 84/280 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- TDRD5 | c.2161-2A>T p.X721_splice | Splice Site (SNP) | VAF 6/42 reads (14%) | called by muse, varscan2
- TGIF2LY | c.317G>T p.R106I | Missense Mutation (SNP) | VAF 95/263 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TLR7 | c.458T>A p.L153H | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TMEM132E | c.2866dup p.W956Lfs*49 (on ENST00000321639; = p.W1046Lfs*49 on NM_001304438.2) | Frame Shift Ins (INS) | VAF 26/151 reads (17%) | called by mutect2, pindel, varscan2
- TMEM214 | c.1917_1918delinsG p.Q640Rfs*12 | Frame Shift Del (DEL) | VAF 36/221 reads (16%) | called by pindel, varscan2*
- TRIM38 | c.412-2A>T p.X138_splice | Splice Site (SNP) | VAF 18/87 reads (21%) | called by muse, mutect2, varscan2
- TRIM42 | c.1176G>T p.K392N | Missense Mutation (SNP) | VAF 55/298 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TRPV1 | c.65C>T p.P22L | Missense Mutation (SNP) | VAF 37/202 reads (18%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- TUBA3E | c.349C>A p.L117I | Missense Mutation (SNP) | VAF 42/156 reads (27%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TUBA3E | c.348C>A p.D116E | Missense Mutation (SNP) | VAF 43/158 reads (27%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- UBASH3B | c.1859G>T p.G620V | Missense Mutation (SNP) | VAF 32/219 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- UBR2 | c.3205G>T p.E1069* | Nonsense Mutation (SNP) | VAF 29/132 reads (22%) | called by muse, varscan2
- UNC80 | c.3983G>T p.S1328I | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.648); called by muse, mutect2, varscan2
- USPL1 | c.1094G>A p.G365E | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- VPS39 | c.1073G>C p.C358S (on ENST00000348544 / NM_001301138.2; = p.C347S on NM_015289.5) | Missense Mutation (SNP) | VAF 29/200 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- VRTN | c.1049G>C p.W350S | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- WDR81 | c.4454_4455del p.A1485Vfs*13 (on ENST00000409644 / NM_001163809.2; = p.A434Vfs*13 on NM_152348.4) | Frame Shift Del (DEL) | VAF 22/124 reads (18%) | called by mutect2, pindel, varscan2
- WDR91 | c.751G>A p.A251T | Missense Mutation (SNP) | VAF 25/139 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- XKR7 | c.1504C>A p.Q502K | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- ZDHHC20 | c.968C>T p.P323L (on ENST00000400590 / NM_001330059.2; = p.P322L on NM_153251.3) | Missense Mutation (SNP) | VAF 41/165 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- ZFHX4 | c.10088C>A p.A3363D | Missense Mutation (SNP) | VAF 44/225 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ZFPM2 | c.1225C>T p.Q409* | Nonsense Mutation (SNP) | VAF 75/407 reads (18%) | called by muse, mutect2, varscan2
- ZFYVE19 | c.571A>G p.K191E (on ENST00000355341 / NM_001077268.2; = p.K181E on NM_032850.5) | Missense Mutation (SNP) | VAF 38/154 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- ZNF425 | c.1086G>T p.E362D | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ZNF592 | c.992G>A p.S331N | Missense Mutation (SNP) | VAF 44/266 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF609 | c.3202A>G p.K1068E | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- ZNF875 | c.68G>C p.C23S | Missense Mutation (SNP) | VAF 60/308 reads (19%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.006); called by muse, varscan2
- ZNF879 | c.494G>T p.G165V | Missense Mutation (SNP) | VAF 36/143 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABCB11 | c.1599G>A p.K533= | Silent (SNP) | VAF 30/135 reads (22%) | called by muse, mutect2, varscan2
- ADAM12 | c.1771C>A p.R591= | Silent (SNP) | VAF 58/414 reads (14%) | catalogued as COSV64114150; called by muse, mutect2, varscan2
- ADAMTS14 | c.2494C>T p.L832= | Silent (SNP) | VAF 46/143 reads (32%) | called by muse, mutect2, varscan2
- AEBP1 | c.3168C>A p.A1056= | Silent (SNP) | VAF 16/112 reads (14%) | called by muse, mutect2, varscan2
- ANK1 | c.3087G>T p.L1029= | Silent (SNP) | VAF 45/230 reads (20%) | called by muse, mutect2, varscan2
- CADPS2 | c.33G>C p.S11= | Silent (SNP) | VAF 43/214 reads (20%) | called by muse, mutect2, varscan2
- CDH5 | c.2028C>A p.P676= | Silent (SNP) | VAF 29/164 reads (18%) | called by muse, mutect2, varscan2
- CNTN6 | c.1137A>T p.S379= | Silent (SNP) | VAF 27/181 reads (15%) | catalogued as COSV100610465; called by muse, mutect2, varscan2
- COL11A1 | c.1428T>C p.R476= | Silent (SNP) | VAF 43/194 reads (22%) | called by muse, mutect2, varscan2
- COL6A2 | c.189G>T p.T63= | Silent (SNP) | VAF 66/276 reads (24%) | catalogued as COSV56017635; called by muse, mutect2, varscan2
- CSMD3 | c.1131T>C p.V377= | Silent (SNP) | VAF 58/305 reads (19%) | catalogued as COSV52342246; called by muse, mutect2, varscan2
- CYP11A1 | c.684C>A p.P228= | Silent (SNP) | VAF 74/292 reads (25%) | called by muse, mutect2, varscan2
- DGKB | c.2097T>C p.D699= | Silent (SNP) | VAF 16/66 reads (24%) | called by muse, varscan2
- DYTN | c.870C>A p.T290= | Silent (SNP) | VAF 73/295 reads (25%) | called by muse, mutect2, varscan2
- ERICH3 | c.597C>T p.P199= | Silent (SNP) | VAF 24/61 reads (39%) | catalogued as COSV58615262; called by muse, mutect2, varscan2
- FAM133A | c.705G>A p.K235= | Silent (SNP) | VAF 3/30 reads (10%) | called by muse, mutect2
- FSTL5 | c.804G>T p.L268= | Silent (SNP) | VAF 33/186 reads (18%) | called by muse, mutect2, varscan2
- GALNT15 | c.753G>A p.G251= | Silent (SNP) | VAF 20/61 reads (33%) | catalogued as rs1269679951; called by muse, mutect2, varscan2
- GLYAT | c.741C>A p.I247= | Silent (SNP) | VAF 34/204 reads (17%) | catalogued as COSV99557427; called by muse, mutect2, varscan2
- GPC1 | c.1536G>T p.T512= | Silent (SNP) | VAF 48/209 reads (23%) | called by muse, mutect2, varscan2
- GPR156 | c.531G>T p.V177= | Silent (SNP) | VAF 38/196 reads (19%) | called by muse, mutect2, varscan2
- GSG1L2 | c.36C>G p.L12= | Silent (SNP) | VAF 26/98 reads (27%) | called by muse, mutect2, varscan2
- HDGFL1 | c.690G>T p.A230= | Silent (SNP) | VAF 9/28 reads (32%) | called by muse, mutect2, varscan2
- HSPA13 | c.1146G>T p.L382= | Silent (SNP) | VAF 22/117 reads (19%) | called by muse, mutect2, varscan2
- IGFBP7 | c.216G>T p.G72= | Silent (SNP) | VAF 6/36 reads (17%) | called by muse, mutect2, varscan2
- KAZN | c.1929G>T p.L643= | Silent (SNP) | VAF 34/171 reads (20%) | called by muse, mutect2, varscan2
- KCNH1 | c.1230C>A p.T410= (on ENST00000271751 / NM_172362.3; = p.T383= on NM_002238.4) | Silent (SNP) | VAF 97/645 reads (15%) | catalogued as COSV99658035; called by muse, mutect2, varscan2
- KCP | c.3693C>T p.A1231= (on ENST00000620378; = p.A1355= on NM_001366122.1) | Silent (SNP) | VAF 50/191 reads (26%) | catalogued as rs1410765588; called by muse, varscan2
- LCE1A | c.300G>A p.G100= | Silent (SNP) | VAF 8/59 reads (14%) | called by muse, mutect2, varscan2
- LEPR | c.1635A>C p.A545= | Silent (SNP) | VAF 27/120 reads (23%) | called by muse, mutect2, varscan2
- LOXHD1 | c.5238C>G p.L1746= (on ENST00000642948; = p.L635= on NM_001145472.3) | Silent (SNP) | VAF 19/86 reads (22%) | called by muse, mutect2, varscan2
- LY6D | c.36T>A p.A12= | Silent (SNP) | VAF 21/115 reads (18%) | called by muse, mutect2, varscan2
- MRAP | c.441C>A p.T147= | Silent (SNP) | VAF 37/165 reads (22%) | called by muse, mutect2, varscan2
- OBSCN | c.9240G>T p.A3080= | Silent (SNP) | VAF 18/91 reads (20%) | called by muse, mutect2, varscan2
- OR2G3 | c.438T>A p.S146= | Silent (SNP) | VAF 43/284 reads (15%) | called by muse, mutect2, varscan2
- P2RX2 | c.1344G>A p.E448= (on ENST00000343948 / NM_170683.4; = p.E350= on NM_012226.5) | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as rs749905641; called by muse, mutect2, varscan2
- PCDHGA10 | c.1995C>A p.T665= | Silent (SNP) | VAF 65/407 reads (16%) | catalogued as COSV54005188; called by muse, mutect2, varscan2
- PER2 | c.81A>T p.P27= | Silent (SNP) | VAF 68/305 reads (22%) | called by muse, mutect2, varscan2
- PKD1L1 | c.1173G>A p.L391= | Silent (SNP) | VAF 48/294 reads (16%) | called by muse, mutect2, varscan2
- RBMXL2 | c.582G>A p.P194= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as rs980083360, COSV60978388; called by muse, varscan2
- RMC1 | c.1359G>A p.A453= | Silent (SNP) | VAF 54/253 reads (21%) | catalogued as rs770542539; called by muse, mutect2, varscan2
- RUNDC3B | c.981T>C p.Y327= | Silent (SNP) | VAF 23/114 reads (20%) | catalogued as rs751486016; called by muse, mutect2, varscan2
- RYR1 | c.1030C>T p.L344= | Silent (SNP) | VAF 61/261 reads (23%) | called by muse, mutect2, varscan2
- RYR2 | c.6279C>T p.D2093= | Silent (SNP) | VAF 49/415 reads (12%) | catalogued as rs771328006, COSV63661917; ClinVar: likely benign; called by muse, mutect2, varscan2
- SAGE1 | c.381C>A p.V127= | Silent (SNP) | VAF 22/63 reads (35%) | called by muse, mutect2, varscan2
- SCN4A | c.4584C>T p.C1528= | Silent (SNP) | VAF 45/199 reads (23%) | called by muse, mutect2, varscan2
- SEMG1 | c.63G>T p.V21= | Silent (SNP) | VAF 26/159 reads (16%) | called by muse, mutect2, varscan2
- SHANK1 | c.5892G>T p.A1964= | Silent (SNP) | VAF 32/128 reads (25%) | called by muse, mutect2
- SLC12A5 | c.3249C>T p.I1083= (on ENST00000454036 / NM_001134771.2; = p.I1060= on NM_020708.5) | Silent (SNP) | VAF 61/239 reads (26%) | catalogued as COSV99275603; called by muse, mutect2, varscan2
- SLC12A7 | c.909G>T p.P303= | Silent (SNP) | VAF 25/88 reads (28%) | called by muse, mutect2
- SLC26A7 | c.186G>T p.V62= | Silent (SNP) | VAF 10/65 reads (15%) | catalogued as COSV52588849; called by muse, mutect2, varscan2
- SLC7A3 | c.1161C>A p.T387= | Silent (SNP) | VAF 88/175 reads (50%) | catalogued as COSV53229837; called by muse, mutect2, varscan2
- ST6GAL2 | c.672G>A p.A224= | Silent (SNP) | VAF 41/145 reads (28%) | catalogued as rs1235331966; called by muse, mutect2, varscan2
- SYT8 | c.1104G>T p.R368= | Silent (SNP) | VAF 16/107 reads (15%) | called by muse, mutect2
- TAF1L | c.4719T>C p.R1573= | Silent (SNP) | VAF 14/87 reads (16%) | called by muse, varscan2
- TAF4 | c.1074G>T p.A358= | Silent (SNP) | VAF 4/22 reads (18%) | called by mutect2, varscan2
- TGIF2LY | c.318A>G p.R106= | Silent (SNP) | VAF 95/263 reads (36%) | called by muse, mutect2, varscan2
- TMEM108 | c.1242G>T p.V414= | Silent (SNP) | VAF 23/109 reads (21%) | catalogued as rs1036361712; called by muse, mutect2, varscan2
- TMEM74B | c.345G>A p.V115= | Silent (SNP) | VAF 16/61 reads (26%) | called by muse, mutect2, varscan2
- TMEM88B | c.207G>C p.V69= | Silent (SNP) | VAF 5/25 reads (20%) | called by muse, mutect2, varscan2
- TMEM94 | c.2925C>T p.F975= | Silent (SNP) | VAF 16/113 reads (14%) | catalogued as rs1343021365, COSV58600970; called by muse, mutect2, varscan2
- TRIM42 | c.462G>T p.L154= | Silent (SNP) | VAF 56/311 reads (18%) | called by muse, mutect2, varscan2
- USP29 | c.1866G>T p.L622= | Silent (SNP) | VAF 31/122 reads (25%) | called by muse, mutect2, varscan2
- VCAN | c.375G>T p.A125= | Silent (SNP) | VAF 41/205 reads (20%) | catalogued as COSV54102101; called by muse, mutect2, varscan2
- VPS37C | c.225G>T p.R75= | Silent (SNP) | VAF 18/77 reads (23%) | called by muse, mutect2, varscan2
- WDR62 | c.747G>A p.E249= | Silent (SNP) | VAF 58/274 reads (21%) | called by muse, mutect2, varscan2
- XRRA1 | c.1995A>G p.K665= | Silent (SNP) | VAF 26/120 reads (22%) | called by muse, mutect2, varscan2
- ZDHHC7 | c.429C>T p.A143= | Silent (SNP) | VAF 54/297 reads (18%) | called by muse, mutect2, varscan2
- ZIC2 | c.132G>A p.A44= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as rs1177831999; called by muse, mutect2
- AC024940.1 | n.4126G>T | RNA (SNP) | VAF 52/270 reads (19%) | called by muse, mutect2, varscan2
- AC024940.1 | n.2643G>A | RNA (SNP) | VAF 19/117 reads (16%) | called by muse, mutect2, varscan2
- AL121757.1 | n.547G>T | RNA (SNP) | VAF 46/198 reads (23%) | called by mutect2, varscan2
- AL355390.1 | n.557C>A | RNA (SNP) | VAF 54/219 reads (25%) | called by muse, mutect2, varscan2
- ANKRD42 | chr11:83194429 G>T | 5'Flank (SNP) | VAF 26/156 reads (17%) | called by muse, mutect2, varscan2
- ATP5MF-PTCD1 | c.-21A>T | 5'UTR (SNP) | VAF 34/136 reads (25%) | called by muse, mutect2, varscan2
- BTNL9 | c.887-363G>C | Intron (SNP) | VAF 59/255 reads (23%) | called by muse, mutect2, varscan2
- C10orf143 | c.69+2505G>T | Intron (SNP) | VAF 91/368 reads (25%) | called by muse, mutect2, varscan2
- C22orf34 | n.308C>A | RNA (SNP) | VAF 63/282 reads (22%) | called by muse, mutect2, varscan2
- C2CD6 | c.1581+2531C>A | Intron (SNP) | VAF 47/231 reads (20%) | called by muse, mutect2, varscan2
- CCDC175 | c.-20C>A | 5'UTR (SNP) | VAF 12/52 reads (23%) | called by muse, mutect2, varscan2
- CDK16 | c.*650A>T | 3'UTR (SNP) | VAF 32/74 reads (43%) | called by muse, mutect2, varscan2
- CSMD3 | c.7885+52C>A | Intron (SNP) | VAF 15/91 reads (16%) | called by muse, mutect2, varscan2
- CTDP1 | chr18:79679461 G>T | 5'Flank (SNP) | VAF 30/202 reads (15%) | called by muse, varscan2
- CTDP1 | chr18:79679500 G>T | 5'Flank (SNP) | VAF 44/210 reads (21%) | called by muse, varscan2
- DLG2 | c.205-65747C>T | Intron (SNP) | VAF 64/344 reads (19%) | catalogued as COSV99715320, COSV99718016; called by muse, mutect2, varscan2
- ELOVL4 | c.*30G>A | 3'UTR (SNP) | VAF 40/214 reads (19%) | catalogued as rs771488579; called by muse, mutect2, varscan2
- FBL | c.942-15A>G | Intron (SNP) | VAF 14/103 reads (14%) | catalogued as rs757402022; called by muse, mutect2, varscan2
- GLP2R | c.*304G>T | 3'UTR (SNP) | VAF 30/188 reads (16%) | called by muse, mutect2, varscan2
- GLRXP3 | n.68G>T | RNA (SNP) | VAF 47/263 reads (18%) | called by muse, mutect2, varscan2
- HHLA1 | c.139+23T>A | Intron (SNP) | VAF 16/93 reads (17%) | called by muse, mutect2, varscan2
- IGFN1 | c.1242-2346G>T | Intron (SNP) | VAF 149/571 reads (26%) | called by muse, mutect2, varscan2
- IGHMBP2 | c.1419-36G>T | Intron (SNP) | VAF 58/297 reads (20%) | called by muse, mutect2, varscan2
- IGLL5 | chr22:22901050 C>A | 3'Flank (SNP) | VAF 94/1139 reads (8%) | catalogued as rs759201934; called by muse, mutect2
- IKBIP | c.297+7834G>A | Intron (SNP) | VAF 16/121 reads (13%) | catalogued as rs553354185; called by muse, mutect2, varscan2
- INTS1 | c.-80G>T | 5'UTR (SNP) | VAF 35/194 reads (18%) | catalogued as rs868049249; called by muse, mutect2, varscan2
- ITPK1 | c.*776del | 3'UTR (DEL) | VAF 8/43 reads (19%) | called by pindel, varscan2
- KLHDC4 | c.99+705G>T | Intron (SNP) | VAF 8/98 reads (8%) | called by muse, mutect2
- KSR1 | c.1510+541A>G | Intron (SNP) | VAF 37/156 reads (24%) | called by muse, mutect2, varscan2
- LAMA4 | c.*3T>A | 3'UTR (SNP) | VAF 115/496 reads (23%) | called by muse, mutect2, varscan2
- LCP2 | c.622-13G>T | Intron (SNP) | VAF 38/143 reads (27%) | called by muse, mutect2, varscan2
- LHX6 | c.-42C>G | 5'UTR (SNP) | VAF 13/44 reads (30%) | called by muse, mutect2, varscan2
- LINC00840 | n.309G>T | RNA (SNP) | VAF 134/408 reads (33%) | called by muse, mutect2, varscan2
- LINC02219 | n.242C>A | RNA (SNP) | VAF 6/30 reads (20%) | called by muse, mutect2
- MC3R | c.-13C>G | 5'UTR (SNP) | VAF 47/233 reads (20%) | called by muse, mutect2, varscan2
- MIR508 | n.22G>T | RNA (SNP) | VAF 30/107 reads (28%) | called by muse, mutect2, varscan2
- MTMR6 | c.726+1005A>G | Intron (SNP) | VAF 22/134 reads (16%) | called by muse, mutect2, varscan2
- NPIPA5 | c.642+511G>C | Intron (SNP) | VAF 13/33 reads (39%) | called by mutect2, varscan2
- NR1H3 | c.43+178C>T | Intron (SNP) | VAF 22/120 reads (18%) | catalogued as COSV68008338; called by muse, mutect2, varscan2
- OR6W1P | n.913G>C | RNA (SNP) | VAF 8/40 reads (20%) | called by muse, mutect2, varscan2
- PAFAH1B1 | c.901-22del | Intron (DEL) | VAF 44/227 reads (19%) | called by mutect2, pindel, varscan2
- PPP2R2C | c.71-148C>A | Intron (SNP) | VAF 22/98 reads (22%) | called by muse, mutect2, varscan2
- R3HDM1 | c.-137A>C | 5'UTR (SNP) | VAF 21/118 reads (18%) | called by muse, mutect2, varscan2
- RAB34 | c.-322G>C | 5'UTR (SNP) | VAF 47/229 reads (21%) | called by muse, mutect2, varscan2
- RNA5S17 | chr1:228650376 C>T | 5'Flank (SNP) | VAF 63/466 reads (14%) | called by muse, mutect2, varscan2
- RNU6-713P | chr12:40558121 C>T | 5'Flank (SNP) | VAF 35/215 reads (16%) | called by muse, mutect2, varscan2
- ROBO2 | c.3761-31C>G | Intron (SNP) | VAF 37/177 reads (21%) | called by muse, mutect2, varscan2
- RPL32P29 | chr14:49577850 C>T | 5'Flank (SNP) | VAF 32/161 reads (20%) | called by muse, mutect2, varscan2
- RUNX1T1 | chr8:92102877 C>A | 5'Flank (SNP) | VAF 24/171 reads (14%) | called by muse, mutect2, varscan2
- SLC25A44 | c.626-9G>C | Intron (SNP) | VAF 18/163 reads (11%) | called by muse, mutect2, varscan2
- SLC7A2 | c.-22-4534dup | Intron (INS) | VAF 27/160 reads (17%) | called by mutect2, pindel, varscan2
- SNORD108 | n.58G>C | RNA (SNP) | VAF 26/163 reads (16%) | called by muse, mutect2, varscan2
- SNORD115-34 | n.64T>A | RNA (SNP) | VAF 80/377 reads (21%) | called by muse, mutect2, varscan2
- SNORD52 | chr6:31837316 G>T | 3'Flank (SNP) | VAF 40/248 reads (16%) | called by muse, mutect2, varscan2
- SSPOP | n.14572G>T | RNA (SNP) | VAF 31/118 reads (26%) | called by muse, mutect2, varscan2
- SSPOP | n.14573G>T | RNA (SNP) | VAF 29/118 reads (25%) | called by muse, mutect2, varscan2
- SUN1 | c.659-289C>A | Intron (SNP) | VAF 11/79 reads (14%) | called by muse, mutect2, varscan2
- SYCP2L | c.-25G>T | 5'UTR (SNP) | VAF 17/113 reads (15%) | catalogued as COSV51649459; called by muse, mutect2, varscan2
- TRIQK | chr8:92884943 C>A | 3'Flank (SNP) | VAF 74/392 reads (19%) | called by muse, mutect2, varscan2
- UGT1A6 | c.862-12209C>A | Intron (SNP) | VAF 69/350 reads (20%) | called by muse, mutect2, varscan2
- USP6 | c.1079-240C>A | Intron (SNP) | VAF 25/89 reads (28%) | called by muse, mutect2, varscan2
- VSTM2A | c.634+3815C>T | Intron (SNP) | VAF 62/353 reads (18%) | catalogued as COSV104403893; called by muse, mutect2, varscan2
- ZEB2 | c.73+4978C>A | Intron (SNP) | VAF 38/247 reads (15%) | called by muse, mutect2, varscan2
- ZNF92 | c.-63C>T | 5'UTR (SNP) | VAF 54/354 reads (15%) | called by muse, mutect2, varscan2
